Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A7XP, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A7XP-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is located in a left hepatic lobe, ill-margins with 4x3.5x3cm in size, soft, solid, yellow-white in cutting section.

Microscopic Description: Tumor cells form the trabecular patterns, or acinar or sheets patterns. The tumor cells retain apolygonal shape and have round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are moderate and the cytoplasm is basophilic or vacuolated. Nuclei are very irregularly large single or multiple and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor infiltrates into benign hepatic tissue. Stroma is invasion of lymphocyte

Diagnosis Details: Hepatocellular carcinoma, poorly-differentiated

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor size: 4 x 3.5 x 3 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Multiple tumors under 5.0 cm

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Left hepatic lobe liver. Tumor infiltrates benign hepatic tissue.

Comments: None

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

Qx 10/10/13

Case is Eligible		

Source: NCI Genomic Data Commons file 6ebc60ca-ea5c-4119-b735-60b24b9d7b3c (TCGA-ED-A7XP.70432A18-BDAF-465D-9311-66E37E3F941E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).